Somatic mutation profile of tumor specimen C3N-03076-02 (aliquot CPT0236420006) from CPTAC case C3N-03076, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 68.0 years (24,846 days).
Specimen C3N-03076-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9f5e87b6-141b-4b99-9059-dc5199759b87.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03076-31 (Blood Derived Normal), aliquot CPT0236470002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cd25b2d2-20a4-4efc-a444-c1c0cc7c2d94

The open-access MAF lists 196 somatic variants for this specimen: 125 protein-altering or splice-affecting, 47 silent, 24 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 108, Silent 47, Intron 11, Splice Site 5, 5'UTR 5, Splice Region 5, Nonsense Mutation 4, 3'UTR 3, 3'Flank 2, 5'Flank 2, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.151-1G>A p.X51_splice | Splice Site (SNP) | VAF 135/369 reads (37%) | hotspot (GDC flag); catalogued as CS014428, CS067079, COSV58682903, COSV58695350, COSV58708670, COSV58717973; called by muse, mutect2, varscan2
- AAGAB | c.680C>T p.S227F | Missense Mutation (SNP) | VAF 46/264 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.353); catalogued as rs761177603; called by muse, mutect2
- AHCY | c.294G>T p.P98= | Splice Region (SNP) | VAF 150/674 reads (22%) | catalogued as rs570467069; called by muse, mutect2, varscan2
- ALMS1 | c.7528G>A p.V2510I | Missense Mutation (SNP) | VAF 47/212 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as CD150641; called by muse, mutect2, varscan2
- ANKRD36C | c.3094A>G p.T1032A | Missense Mutation (SNP) | VAF 76/301 reads (25%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.518); catalogued as rs1394504425; called by muse, mutect2, varscan2
- ATP2C2 | c.1478C>T p.A493V | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.218); catalogued as rs531822897, COSV52294612, COSV52299276; called by muse, mutect2, varscan2
- B4GALT6 | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 13/146 reads (9%) | SIFT tolerated (0.64); PolyPhen benign (0.364); catalogued as rs915348123; called by muse, mutect2
- BARHL2 | c.371C>T p.P124L | Missense Mutation (SNP) | VAF 42/240 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.011); catalogued as rs752327071; called by mutect2, varscan2
- BLK | c.667C>G p.P223A | Missense Mutation (SNP) | VAF 155/374 reads (41%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV52050157; called by muse, mutect2, varscan2
- CDK13 | c.2579G>C p.R860P | Missense Mutation (SNP) | VAF 48/142 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51702733; called by muse, mutect2, varscan2
- CHST13 | c.404C>T p.P135L | Missense Mutation (SNP) | VAF 36/398 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100081319; called by muse, mutect2
- COL12A1 | c.557C>G p.S186C | Missense Mutation (SNP) | VAF 51/328 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.746); catalogued as COSV59394435; called by muse, mutect2, varscan2
- CR2 | c.820A>G p.I274V | Missense Mutation (SNP) | VAF 43/244 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV65505879; called by muse, mutect2, varscan2
- CRMP1 | c.1412G>A p.R471Q | Missense Mutation (SNP) | VAF 36/229 reads (16%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.978); catalogued as rs768763171; called by muse, mutect2, varscan2
- ECI1 | c.644C>T p.A215V | Missense Mutation (SNP) | VAF 32/304 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.067); catalogued as rs768697158; called by muse, mutect2, varscan2
- FBN1 | c.6797A>G p.K2266R | Missense Mutation (SNP) | VAF 103/397 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1566894294; called by muse, mutect2, varscan2
- FGFR3 | c.*701G>C | Splice Region (SNP) | VAF 42/258 reads (16%) | catalogued as COSV99603159; called by muse, mutect2, varscan2
- GRAMD1B | c.281G>T p.R94I | Missense Mutation (SNP) | VAF 68/268 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59202909; called by muse, mutect2, varscan2
- HSPA12A | c.1508G>A p.R503Q | Missense Mutation (SNP) | VAF 18/396 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs782470572, COSV100979797; called by muse, mutect2
- HSPG2 | c.1762C>T p.R588C | Missense Mutation (SNP) | VAF 49/316 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs778444704; called by muse, mutect2, varscan2
- KRTAP25-1 | c.94C>T p.R32C | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as rs769869352, COSV101342659; called by muse, mutect2, varscan2
- LMAN2L | c.583A>G p.T195A | Missense Mutation (SNP) | VAF 104/398 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as rs1236620247, COSV53842970; called by muse, mutect2, varscan2
- LRRC3B | c.448G>A p.D150N | Missense Mutation (SNP) | VAF 62/179 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.259); catalogued as rs1352026072; called by muse, mutect2, varscan2
- LSM11 | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 46/233 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs771232721; called by muse, mutect2, varscan2
- MCRS1 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 53/346 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.089); catalogued as COSV59459208; called by muse, mutect2, varscan2
- MFHAS1 | c.68G>A p.R23K | Missense Mutation (SNP) | VAF 43/220 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.899); catalogued as rs1489663745; called by muse, mutect2, varscan2
- MGRN1 | c.542C>T p.S181L | Missense Mutation (SNP) | VAF 16/250 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs754962642; called by muse, mutect2
- MPC1 | c.212A>G p.Y71C | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.076); catalogued as rs374078299; called by muse, mutect2, varscan2
- MYH7 | c.1301G>A p.R434K | Missense Mutation (SNP) | VAF 117/652 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs786205356, CM1412206, COSV62516253; ClinVar: benign / likely benign; called by muse, mutect2, varscan2
- NCDN | c.2096G>A p.R699Q | Missense Mutation (SNP) | VAF 38/343 reads (11%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as rs1384220448; called by muse, mutect2, varscan2
- NLRP11 | c.962C>G p.A321G | Missense Mutation (SNP) | VAF 37/193 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV100789753; called by muse, mutect2, varscan2
- NTRK3 | c.2204G>A p.R735H (on ENST00000360948 / NM_001012338.2; = p.R721H on NM_002530.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/373 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62297428; called by muse, mutect2, varscan2
- OR1S1 | c.364G>A p.V122I | Missense Mutation (SNP) | VAF 98/388 reads (25%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs147498041; called by muse, varscan2
- OR56B4 | c.309T>G p.C103W | Missense Mutation (SNP) | VAF 50/308 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57204515; called by muse, mutect2, varscan2
- PCDHB16 | c.2035G>A p.G679S | Missense Mutation (SNP) | VAF 240/657 reads (37%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs201005937; called by muse, mutect2, varscan2
- PDZD4 | c.1067G>A p.R356H | Missense Mutation (SNP) | VAF 65/146 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV51246601; called by muse, mutect2, varscan2
- PDZRN3 | c.1654G>A p.G552S | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.528); catalogued as rs143580910; called by muse, mutect2, varscan2
- PKHD1 | c.1690C>T p.R564* | Nonsense Mutation (SNP) | VAF 47/383 reads (12%) | catalogued as rs765251347, CM100548, COSV61885249; called by muse, mutect2, varscan2
- PKHD1L1 | c.9395G>T p.G3132V | Missense Mutation (SNP) | VAF 14/141 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV65748973; called by muse, mutect2
- PSD4 | c.3023G>A p.R1008Q | Missense Mutation (SNP) | VAF 33/322 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200368046; called by muse, mutect2, varscan2
- RNPS1 | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.09); catalogued as rs757501400; called by muse, mutect2
- SGO2 | c.1952A>G p.Q651R | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.64); catalogued as rs781510633; called by muse, mutect2, varscan2
- SHH | c.1307C>G p.S436W | Missense Mutation (SNP) | VAF 23/152 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM992973, COSV51918396; called by muse, mutect2, varscan2
- SOX1 | c.288G>C p.E96D | Missense Mutation (SNP) | VAF 48/450 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as rs373278017; called by muse, mutect2, varscan2
- TBRG1 | c.673A>C p.M225L | Missense Mutation (SNP) | VAF 62/259 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.014); catalogued as COSV52515065; called by muse, mutect2, varscan2
- TRAPPC2L | c.193G>C p.E65Q | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51936393; called by muse, mutect2, varscan2
- TSC2 | c.3802C>T p.R1268C | Missense Mutation (SNP) | VAF 180/596 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs1020561347, COSV54779754, COSV54785836; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUFM | c.851G>A p.R284H | Missense Mutation (SNP) | VAF 125/846 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as rs779228479, COSV57948554, COSV57949231; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TXNL1 | c.28G>A p.D10N | Missense Mutation (SNP) | VAF 20/212 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.28); catalogued as COSV54179209; called by muse, mutect2
- UBXN2B | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 24/203 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.164); catalogued as COSV68308964; called by muse, mutect2, varscan2
- VPS13B | c.11243G>A p.G3748D | Missense Mutation (SNP) | VAF 35/347 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV62150247; called by muse, mutect2
- ZFHX4 | c.2495C>G p.T832S | Missense Mutation (SNP) | VAF 50/236 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.197); catalogued as COSV99267209; called by muse, mutect2, varscan2
- ZFPM2 | c.2700C>A p.S900R | Missense Mutation (SNP) | VAF 206/613 reads (34%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.737); catalogued as COSV65872734; called by muse, mutect2, varscan2
- ZNF236 | c.638C>T p.T213M | Missense Mutation (SNP) | VAF 34/202 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.947); catalogued as rs765449044; called by muse, mutect2, varscan2
- ZNF721 | c.605T>C p.I202T (on ENST00000338977; = p.I214T on NM_133474.4) | Missense Mutation (SNP) | VAF 66/327 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.954); catalogued as rs782742309; called by muse, mutect2, varscan2
- ZNF780B | c.694C>A p.L232I | Missense Mutation (SNP) | VAF 27/156 reads (17%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.783); catalogued as rs766203771; called by muse, mutect2, varscan2
- ABCB1 | c.139G>C p.D47H | Missense Mutation (SNP) | VAF 22/205 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACTN2 | c.2143T>A p.Y715N | Missense Mutation (SNP) | VAF 141/408 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ADCY9 | c.2092G>A p.E698K | Missense Mutation (SNP) | VAF 49/332 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- ADGRE1 | c.2354C>A p.A785D | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- ADRA1D | c.1493G>T p.R498M | Missense Mutation (SNP) | VAF 75/308 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- AKAP11 | c.4882C>G p.Q1628E | Missense Mutation (SNP) | VAF 19/153 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- C10orf90 | c.127C>G p.R43G | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.039); called by muse, mutect2
- C12orf50 | c.1024G>A p.V342I | Missense Mutation (SNP) | VAF 43/368 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- C3orf56 | c.521C>T p.S174F | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- CCDC40 | c.126A>C p.K42N | Missense Mutation (SNP) | VAF 69/235 reads (29%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CCDC57 | c.341A>G p.E114G | Missense Mutation (SNP) | VAF 28/206 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- CDC40 | c.1265A>G p.N422S | Missense Mutation (SNP) | VAF 16/208 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); called by muse, mutect2
- CKB | c.483C>A p.A161= | Splice Region (SNP) | VAF 18/96 reads (19%) | called by muse, mutect2, varscan2
- CLIC5 | c.605G>T p.W202L (on ENST00000185206 / NM_001370649.1; = p.W43L on NM_016929.5) | Missense Mutation (SNP) | VAF 17/204 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.87); called by muse, mutect2
- CNRIP1 | c.433T>A p.Y145N | Missense Mutation (SNP) | VAF 54/190 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- CPNE7 | c.259C>A p.Q87K | Missense Mutation (SNP) | VAF 50/289 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CROCC | c.5555G>T p.R1852L | Missense Mutation (SNP) | VAF 74/253 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- DDN | c.1897G>A p.E633K | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- DLG2 | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 24/241 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.832); called by muse, mutect2
- DOCK10 | c.1189A>T p.I397F | Missense Mutation (SNP) | VAF 49/147 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- DZIP3 | c.209C>G p.P70R | Missense Mutation (SNP) | VAF 57/208 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ECI1 | c.564-3C>T | Splice Region (SNP) | VAF 83/544 reads (15%) | called by muse, mutect2, varscan2
- EIF4G3 | c.3086G>T p.R1029I | Missense Mutation (SNP) | VAF 28/230 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- EVC2 | c.143G>T p.R48L | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- EXOC8 | c.1987C>T p.R663* | Nonsense Mutation (SNP) | VAF 41/187 reads (22%) | called by muse, mutect2, varscan2
- FLAD1 | c.1427C>T p.A476V | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GABRA2 | c.1130A>T p.N377I | Missense Mutation (SNP) | VAF 67/159 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- GULP1 | c.517-2A>G p.X173_splice | Splice Site (SNP) | VAF 16/73 reads (22%) | called by muse, mutect2
- HDAC9 | c.77T>A p.L26Q | Missense Mutation (SNP) | VAF 46/267 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HRNR | c.507T>A p.H169Q | Missense Mutation (SNP) | VAF 68/411 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IGKV1-16 | c.122_123insG p.T42Hfs*11 | Frame Shift Ins (INS) | VAF 127/777 reads (16%) | called by pindel, varscan2
- IGKV1D-8 | c.167C>G p.A56G | Missense Mutation (SNP) | VAF 50/439 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- KLHL42 | c.419A>G p.Y140C | Missense Mutation (SNP) | VAF 57/204 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- KRT8 | c.719C>T p.S240L | Missense Mutation (SNP) | VAF 35/262 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- MACF1 | c.15317T>G p.L5106R (on ENST00000372915; = p.L3039R on NM_012090.5) | Missense Mutation (SNP) | VAF 31/218 reads (14%) | called by muse, mutect2, varscan2
- MEGF8 | c.6772C>T p.H2258Y (on ENST00000251268 / NM_001271938.2; = p.H2191Y on NM_001410.3) | Missense Mutation (SNP) | VAF 77/222 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MIEF1 | c.278G>T p.R93L | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- MMS22L | c.1432A>C p.S478R | Missense Mutation (SNP) | VAF 44/254 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- MOGAT3 | c.392G>A p.S131N | Missense Mutation (SNP) | VAF 38/472 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.316); called by muse, mutect2
- MS4A14 | c.1097C>A p.S366* | Nonsense Mutation (SNP) | VAF 61/238 reads (26%) | called by muse, mutect2, varscan2
- MYO9A | c.1426G>T p.V476L | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.475); called by muse, mutect2
- NOS3 | c.1541_1555del p.M514_V518del | In Frame Del (DEL) | VAF 32/338 reads (9%) | called by mutect2, pindel
- NRCAM | c.2232A>G p.S744= (on ENST00000379028 / NM_001371124.1; = p.S728= on NM_005010.4 and 21 other RefSeq transcripts) | Splice Region (SNP) | VAF 66/312 reads (21%) | called by muse, mutect2, varscan2
- OR8B12 | c.401C>T p.T134I | Missense Mutation (SNP) | VAF 56/184 reads (30%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- PERM1 | c.834C>A p.H278Q | Missense Mutation (SNP) | VAF 43/309 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- PERM1 | c.833A>T p.H278L | Missense Mutation (SNP) | VAF 46/318 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- PHC2 | c.2146-1G>A p.X716_splice (on ENST00000257118 / NM_198040.2; = p.X181_splice on NM_004427.4) | Splice Site (SNP) | VAF 24/92 reads (26%) | called by muse, mutect2, varscan2
- PRRC2B | c.4729G>A p.E1577K | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.551); called by muse, mutect2, varscan2
- PTPN4 | c.649T>C p.Y217H | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTPRN | c.770C>A p.P257H | Missense Mutation (SNP) | VAF 341/830 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- RAP1GDS1 | c.594_595del p.T199Rfs*9 (on ENST00000408927 / NM_001100427.2; = p.T200Rfs*9 on NM_021159.5) | Frame Shift Del (DEL) | VAF 22/184 reads (12%) | called by mutect2, pindel, varscan2
- RBMX2 | c.410G>T p.G137V | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- RELN | c.6672-1_6693del p.X2224_splice | Splice Site (DEL) | VAF 30/296 reads (10%) | called by mutect2, pindel
- SCP2 | c.1507G>A p.D503N | Missense Mutation (SNP) | VAF 40/292 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SERTM1 | c.294G>C p.Q98H | Missense Mutation (SNP) | VAF 22/165 reads (13%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.005); called by muse, mutect2
- SLC44A1 | c.1202C>T p.A401V | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- SLC4A3 | c.1150C>G p.L384V | Missense Mutation (SNP) | VAF 87/213 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- SMARCC2 | c.112-1G>C p.X38_splice | Splice Site (SNP) | VAF 47/104 reads (45%) | called by muse, mutect2, varscan2
- SYNE1 | c.6753G>C p.L2251F (on ENST00000367255 / NM_182961.4; = p.L2258F on NM_033071.3) | Missense Mutation (SNP) | VAF 74/264 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.426); called by muse, mutect2, varscan2
- TECTA | c.5803G>C p.A1935P | Missense Mutation (SNP) | VAF 148/540 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- TENM3 | c.1693C>A p.L565M | Missense Mutation (SNP) | VAF 50/245 reads (20%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- TNPO2 | c.160A>G p.R54G | Missense Mutation (SNP) | VAF 18/186 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TNXB | c.10315C>A p.R3439S (on ENST00000647633; = p.R3192S on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 234/555 reads (42%) | SIFT tolerated (0.79); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- USP49 | c.473G>A p.W158* | Nonsense Mutation (SNP) | VAF 74/216 reads (34%) | called by muse, mutect2, varscan2
- VAT1L | c.73G>T p.A25S | Missense Mutation (SNP) | VAF 50/307 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- VWA7 | c.1772C>A p.P591H | Missense Mutation (SNP) | VAF 24/175 reads (14%) | SIFT tolerated (0.55); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- WWC1 | c.3178G>A p.E1060K | Missense Mutation (SNP) | VAF 25/168 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- ZNF696 | c.970G>T p.G324C | Missense Mutation (SNP) | VAF 93/248 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- ZSCAN4 | c.873C>A p.S291R | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ABCB6 | c.90G>T p.T30= | Silent (SNP) | VAF 90/444 reads (20%) | catalogued as rs759996497; called by muse, mutect2
- AGTR1 | c.1020C>T p.R340= | Silent (SNP) | VAF 10/262 reads (4%) | called by muse, mutect2
- ANAPC1 | c.4560G>T p.L1520= | Silent (SNP) | VAF 76/272 reads (28%) | called by muse, mutect2, varscan2
- ANKRD33B | c.939G>A p.T313= | Silent (SNP) | VAF 29/229 reads (13%) | called by muse, mutect2, varscan2
- ANO4 | c.369T>C p.L123= (on ENST00000392977 / NM_001286615.2; = p.L88= on NM_178826.4) | Silent (SNP) | VAF 54/228 reads (24%) | called by muse, mutect2, varscan2
- APLP2 | c.1074T>A p.A358= | Silent (SNP) | VAF 29/127 reads (23%) | called by muse, mutect2, varscan2
- C2orf76 | c.190C>T p.L64= | Silent (SNP) | VAF 6/80 reads (8%) | called by muse, mutect2
- CHRM2 | c.1338C>A p.T446= | Silent (SNP) | VAF 31/175 reads (18%) | catalogued as COSV57785127; called by muse, mutect2, varscan2
- CNTRL | c.6216G>A p.Q2072= | Silent (SNP) | VAF 45/250 reads (18%) | called by muse, mutect2, varscan2
- COPS7B | c.367C>A p.R123= | Silent (SNP) | VAF 79/249 reads (32%) | catalogued as rs1278307651; called by muse, mutect2, varscan2
- DNAH6 | c.3747T>A p.V1249= | Silent (SNP) | VAF 49/344 reads (14%) | called by muse, mutect2, varscan2
- ELAPOR1 | c.333C>T p.C111= | Silent (SNP) | VAF 24/188 reads (13%) | catalogued as rs758125698; called by muse, mutect2, varscan2
- ENPP3 | c.94C>T p.L32= | Silent (SNP) | VAF 31/203 reads (15%) | called by muse, mutect2, varscan2
- F2 | c.1254C>T p.T418= | Silent (SNP) | VAF 86/574 reads (15%) | catalogued as rs375752222; called by muse, mutect2, varscan2
- FAM83B | c.840C>T p.S280= | Silent (SNP) | VAF 25/216 reads (12%) | called by muse, mutect2, varscan2
- FLG | c.5376C>A p.S1792= | Silent (SNP) | VAF 70/528 reads (13%) | catalogued as rs1328728912; called by muse, mutect2, varscan2
- FMN2 | c.3348G>C p.A1116= | Silent (SNP) | VAF 10/63 reads (16%) | called by muse, varscan2
- GLG1 | c.1677G>C p.L559= | Silent (SNP) | VAF 80/184 reads (43%) | called by muse, mutect2, varscan2
- H3C8 | c.132C>T p.P44= | Silent (SNP) | VAF 161/417 reads (39%) | catalogued as rs994322247; called by muse, mutect2, varscan2
- HMGB2 | c.603G>A p.E201= | Silent (SNP) | VAF 36/199 reads (18%) | called by muse, mutect2, varscan2
- HSD17B1 | c.237C>A p.R79= | Silent (SNP) | VAF 83/518 reads (16%) | called by muse, mutect2, varscan2
- HTR5A | c.603C>A p.A201= | Silent (SNP) | VAF 118/471 reads (25%) | called by muse, mutect2, varscan2
- LMNTD1 | c.45C>G p.V15= | Silent (SNP) | VAF 73/267 reads (27%) | called by muse, mutect2, varscan2
- MAP4K4 | c.1179A>G p.A393= | Silent (SNP) | VAF 52/244 reads (21%) | called by muse, mutect2, varscan2
- NAT10 | c.612C>G p.L204= | Silent (SNP) | VAF 26/158 reads (16%) | catalogued as COSV57666317; called by muse, mutect2, varscan2
- NDST2 | c.2388T>C p.G796= | Silent (SNP) | VAF 31/221 reads (14%) | called by muse, mutect2, varscan2
- NLGN1 | c.2175A>T p.A725= | Silent (SNP) | VAF 57/251 reads (23%) | called by muse, mutect2, varscan2
- OR4C46 | c.81T>A p.V27= | Silent (SNP) | VAF 38/320 reads (12%) | called by muse, mutect2, varscan2
- OR6T1 | c.168C>T p.H56= | Silent (SNP) | VAF 95/294 reads (32%) | called by muse, mutect2, varscan2
- PERP | c.16C>T p.L6= | Silent (SNP) | VAF 20/148 reads (14%) | called by muse, mutect2, varscan2
- PRODH2 | c.1014G>A p.P338= (on ENST00000301175; = p.P262= on NM_021232.2 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 51/296 reads (17%) | catalogued as rs139352995, COSV99995172; called by muse, mutect2, varscan2
- RAB23 | c.324A>T p.V108= | Silent (SNP) | VAF 22/388 reads (6%) | called by muse, mutect2
- RBMXL2 | c.702G>C p.S234= | Silent (SNP) | VAF 40/109 reads (37%) | catalogued as COSV60978927; called by muse, mutect2, varscan2
- RGS12 | c.1236C>T p.A412= | Silent (SNP) | VAF 83/314 reads (26%) | catalogued as rs1471871638; called by muse, mutect2, varscan2
- SLC7A5 | c.822G>T p.L274= | Silent (SNP) | VAF 79/671 reads (12%) | catalogued as COSV55363063; called by muse, mutect2, varscan2
- SMYD1 | c.1054C>A p.R352= | Silent (SNP) | VAF 42/193 reads (22%) | catalogued as COSV70225397; called by muse, mutect2, varscan2
- SPATA31D1 | c.318T>A p.V106= | Silent (SNP) | VAF 9/207 reads (4%) | called by muse, mutect2
- STAT1 | c.876C>T p.D292= | Silent (SNP) | VAF 122/495 reads (25%) | catalogued as COSV61189736; called by muse, mutect2, varscan2
- SYNM | c.2859C>T p.I953= | Silent (SNP) | VAF 25/533 reads (5%) | catalogued as rs1264104925; called by muse, mutect2
- TADA2A | c.1113T>C p.P371= | Silent (SNP) | VAF 22/375 reads (6%) | called by muse, mutect2
- TCF25 | c.714G>C p.L238= | Silent (SNP) | VAF 39/187 reads (21%) | called by muse, mutect2, varscan2
- TEAD4 | c.1143T>G p.P381= | Silent (SNP) | VAF 69/232 reads (30%) | called by muse, mutect2, varscan2
- TIMP2 | c.12G>T p.A4= | Silent (SNP) | VAF 9/25 reads (36%) | called by muse, mutect2, varscan2
- TLE4 | c.288A>T p.A96= | Silent (SNP) | VAF 65/179 reads (36%) | called by muse, mutect2, varscan2
- WDR7 | c.1059G>A p.L353= | Silent (SNP) | VAF 6/86 reads (7%) | called by muse, mutect2
- ZC3H15 | c.232T>C p.L78= | Silent (SNP) | VAF 27/134 reads (20%) | called by muse, mutect2, varscan2
- ZNF835 | c.660G>T p.R220= | Silent (SNP) | VAF 62/410 reads (15%) | called by muse, mutect2, varscan2
- ADGRD1 | c.1474-5948G>T | Intron (SNP) | VAF 25/177 reads (14%) | called by muse, mutect2, varscan2
- BRD2 | c.-960del | 5'UTR (DEL) | VAF 84/324 reads (26%) | catalogued as rs34330235; called by mutect2, pindel, varscan2
- CDIN1 | c.716+46125A>C | Intron (SNP) | VAF 44/193 reads (23%) | called by muse, mutect2, varscan2
- CRIP2 | chr14:105473305 C>G | 5'Flank (SNP) | VAF 63/295 reads (21%) | called by muse, mutect2, varscan2
- DMKN | c.1039-556G>C | Intron (SNP) | VAF 10/152 reads (7%) | called by muse, mutect2
- DYNC2LI1 | c.993+11A>C | Intron (SNP) | VAF 18/89 reads (20%) | called by muse, mutect2
- GOLGA6L2 | c.*164C>T | 3'UTR (SNP) | VAF 33/125 reads (26%) | catalogued as rs1323880958; called by muse, mutect2, varscan2
- LIMS2 | c.660+42G>T | Intron (SNP) | VAF 33/110 reads (30%) | called by muse, mutect2, varscan2
- LRP1B | c.-55dup | 5'UTR (INS) | VAF 50/246 reads (20%) | called by mutect2, pindel, varscan2
- LVRN | c.*12C>T | 3'UTR (SNP) | VAF 34/160 reads (21%) | catalogued as rs770370826; called by muse, mutect2, varscan2
- MED25 | c.-5G>T | 5'UTR (SNP) | VAF 41/138 reads (30%) | catalogued as rs1423184002; called by muse, mutect2, varscan2
- MUC2 | chr11:1099278 G>A | 3'Flank (SNP) | VAF 27/242 reads (11%) | catalogued as rs1447403178; called by mutect2, varscan2
- MYL2 | c.-14G>T | 5'UTR (SNP) | VAF 102/410 reads (25%) | called by muse, mutect2, varscan2
- NDRG1 | c.-18-521G>T | Intron (SNP) | VAF 44/172 reads (26%) | called by muse, mutect2, varscan2
- OR2W5 | n.581C>A | RNA (SNP) | VAF 163/456 reads (36%) | called by muse, mutect2, varscan2
- PCDHB6 | chr5:141157527 A>G | 3'Flank (SNP) | VAF 260/716 reads (36%) | called by muse, mutect2, varscan2
- PGGT1B | c.*11A>G | 3'UTR (SNP) | VAF 51/138 reads (37%) | catalogued as COSV56973776; called by muse, mutect2, varscan2
- PKD1 | c.7210-29C>T | Intron (SNP) | VAF 71/460 reads (15%) | catalogued as rs772529568; called by muse, mutect2, varscan2
- POMT1 | c.1892-49C>T | Intron (SNP) | VAF 52/124 reads (42%) | catalogued as rs1338275795; called by muse, mutect2, varscan2
- PPARGC1B | c.-22A>G | 5'UTR (SNP) | VAF 39/117 reads (33%) | called by muse, mutect2, varscan2
- SCN3A | c.4537-33T>C | Intron (SNP) | VAF 10/96 reads (10%) | catalogued as rs549275062; called by muse, mutect2, varscan2
- SNED1 | c.3590-33C>A | Intron (SNP) | VAF 46/221 reads (21%) | called by muse, mutect2, varscan2
- SYNE1 | c.4461+10T>C | Intron (SNP) | VAF 59/201 reads (29%) | called by muse, mutect2, varscan2
- TRHDE | chr12:72271904 C>T | 5'Flank (SNP) | VAF 11/224 reads (5%) | catalogued as rs1194899367; called by muse, mutect2
